Somatic mutation profile of tumor specimen TCGA-AA-3522-01A (aliquot TCGA-AA-3522-01A-01W-0831-10) from TCGA case TCGA-AA-3522, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 67.5 years (24,653 days).
Specimen TCGA-AA-3522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6565cb20-16f6-4db9-ac7e-0664a63775d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3522-10A (Blood Derived Normal), aliquot TCGA-AA-3522-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1c515f8-a682-4dd2-812d-b2bebb9fbc0c

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQR | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1344740462, COSV50043080, COSV99334049; called by muse, mutect2, varscan2
- ASTL | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753572086, COSV60903643, COSV60905564; called by muse, mutect2, varscan2
- CACNG8 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.072); catalogued as rs1221818237, COSV99555028, COSV99555154; called by muse, varscan2
- CHST8 | c.934G>A p.V312I | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1323223467, COSV99381178; called by muse, mutect2, varscan2
- CTNNA2 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.136); catalogued as rs765394694, COSV100561245, COSV58152576; called by muse, mutect2, varscan2
- DCLK3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs370066933; called by muse, mutect2
- DEFB116 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 201/926 reads (22%) | catalogued as COSV101269233; called by muse, mutect2, varscan2
- FUT5 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as rs143372058; called by muse, mutect2
- HAVCR1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 137/726 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as rs150731397; called by muse, varscan2
- HOOK2 | c.2016G>A p.M672I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99244202, COSV99244442; called by muse, mutect2, varscan2
- JPT2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs906555620, COSV99936125; called by muse, mutect2, varscan2
- KNL1 | c.571C>T p.L191F (on ENST00000346991 / NM_170589.5; = p.L165F on NM_144508.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100706586; called by muse, mutect2, varscan2
- LAMA4 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.221); catalogued as rs1272214897, COSV54570298; called by muse, mutect2, varscan2
- MAP1A | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100288744; called by muse, mutect2, varscan2
- PIK3CA | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as COSV55889532, COSV99837137; called by muse, mutect2, varscan2
- VTN | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1392405498, COSV99879602; called by muse, mutect2
- SYP | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- TM2D3 | c.70T>C p.F24L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- BORCS6 | c.790C>T p.L264= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1316718623, COSV101198012; called by muse, mutect2
- DCAF12L2 | c.844T>C p.L282= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100758643, COSV63584613; called by muse, mutect2, varscan2
- FIGN | c.1374C>T p.D458= | Silent (SNP) | VAF 54/592 reads (9%) | catalogued as rs769689570, COSV100292462; called by muse, mutect2
- PIF1 | c.1800G>A p.A600= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs375126018; called by muse, mutect2, varscan2
- RTP5 | c.144G>T p.L48= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100574746; called by mutect2, varscan2
- SLC39A7 | c.366T>G p.A122= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100807719; called by muse, mutect2, varscan2
- VWA8 | c.3237T>G p.L1079= | Silent (SNP) | VAF 54/251 reads (22%) | catalogued as COSV101022731; called by muse, mutect2, varscan2
